Surgical pathology report (de-identified scan), TCGA case TCGA-A4-A5Y1, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A4-A5Y1-01A (Primary Tumor).

[page 1 of 4]
Age: Sex: M

Laboratory Patient Report
Print Date/Time:

Surgical Pathology

*ICD-O-3
Carcinoma, papillary renal
cell 8260/3
Site @ Kidney NOS. C64.9
JW 5/10/13*

Histopathological Examination

Collected:

Received:

Complete:

Pre-Op Diagnosis : Left Renal Cancer, Enlargement Of Lymph Nodes

Order Physician : [REDACTED]

Specimens : Kidney, left for
Omental Biopsy
Lymph Node, Left Pelvic

Frozen Diagnosis :

Report : GROSS EXAMINATION:

A. The specimen is received fresh in a container labeled with the name of the patient and as kidney, left.

Size: 14.5 x 8 x 7 cm

Weight: 386 g

Perinephric fat: Moderate amount attached

Ureter dimensions: 3.5 x 0.7 cm

Tumor:

Size: 5.5 x 5 x 4.3 cm

Description: Friable, tan-pink, and hemorrhagic

Location: Mainly in the mid pole with no involvement of extreme upper or lower poles

Extent:

Capsule/perinephric fat: Uninvolved

Renal sinus: Possibly involved

Pelvis/calices: Uninvolved/calices involved

Renal vein: Uninvolved

Adrenal: Absent

Distance to margins:

Gerota's fascia: 0.3 cm

Ureteral: 7 cm

Hilar: 2 cm

Renal vein: 1.6 cm

Adrenal: Absent

Lymph nodes: No

Ink code: Gerota's fascia-black, hilar soft tissue margin-green

Representative sections are submitted:

A1. Ureteral and vascular margins, en face

A2. Hilar soft tissue margin, en face

[page 2 of 4]
Visit #: [REDACTED]

- A3. Tumor and renal sinus
- A4-A5. Tumor and calyces
- A6. Tumor and Gerota's fascia
- A7. Tumor with adjacent parenchyma
- A8. Remaining parenchyma
- [REDACTED]

B. The specimen is received labeled with the name of the patient and as omental mass. It consists of an irregular portion of soft tan-brown tissue and attached fat measuring 2.5 x 1.5 x 1.1 cm. The specimen is inked blue. Cut sections reveal a red-brown cut surface. The specimen is entirely submitted in B1-B3.

C. The specimen is received labeled with the name of the patient and as lymph node, left pelvic. It consists of two irregular pieces of soft tan-brown tissue measuring 3 x 1.6 x 1.3 cm. The specimen is serially sectioned and entirely submitted in C1-C5. [REDACTED]

MICROSCOPIC EXAMINATION:

Sections of the grossly identified renal tumor show carcinoma with papillary morphology. The tumor is characterized by multinodular growth and tumor cells with moderately pleomorphic medium to large oval nuclei with occasional nuclear grooves and ample eosinophilic to vacuolated cytoplasm. In areas the papillary formations are densely packed and essentially solid. There is multifocal intratumoral hemosiderin and formation of cystic nodules filled with papillary tumor and blood. Tumor abuts the fibrous renal capsule, but does not clearly invade perirenal fat on multiple levels examined. There is invasion of small non-muscularized veins in the renal sinus but no definitive invasion of the renal sinus fat or large branches of the renal vein.

The tumor is associated with a significant and extensive diffuse and nodular lymphocytic infiltrate at the periphery of the lesion that also extensively involve perinephric and renal sinus fat, and show sheets and nodules of cells extensively involve the remaining non-carcinomatous renal cortex. These are monomorphic-appearing small lymphocytes, and by immunohistochemistry are diffusely positive for CD20 and BCL-2. The same B cells are negative for CD5 and CD23, which highlights residual germinal center dendritic cells. CD3 and CD5 show staining in a smaller population of T lymphocytes. BCL-6 and cyclin D1 are negative.

Sections of the omental nodule show a spherical accessory spleen with relatively normal splenic architecture and small periarterial lymphoid nodules. The adipose tissue surrounding the splenule is involved by dense sheets and nodules of the same lymphoid infiltrate with identical

[page 3 of 4]
immunophenotype to the kidney. The left pelvic lymph node shows involvement by both metastatic papillary carcinoma and the same abnormal lymphoid population, with near complete effacement of residual normal nodal architecture in the

THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Page 2 of 4

Visit #: [REDACTED]

non-carcinomatous areas. Positive and negative control slides are appropriate.

DIAGNOSIS BASED ON GROSS AND MICROSCOPIC EXAMINATION:

A. Kidney, left, radical nephrectomy:

- Papillary renal cell carcinoma (histologic type 2), 5.5 cm in greatest dimension.
- Carcinoma is confined to the kidney, without invasion of renal sinus fat, muscularized branches of the renal vein, or perinephric fat.
- Carcinoma shows invasion of small non-muscularized vessels in renal sinus.
- Small B-cell lymphoma most consistent with extranodal marginal zone lymphoma, with diffuse involvement of kidney, perinephric fat, and renal sinus.
- Ureter, vascular, and soft tissue resection margins are negative for carcinoma.
- See

B. Omentum, excisional biopsy of mass:

- Accessory spleen, with surrounding adipose tissue involved by small B-cell lymphoma.

C. Lymph node, left pelvic, excision:

- One lymph node, involved by both metastatic papillary renal cell carcinoma and small B-cell lymphoma.

CANCER CASE SUMMARY

KIDNEY: Resection (Version 3.0.0.0.)

SPECIMEN PROCEDURE: Left radical nephrectomy

TUMOR SITE: Middle

TUMOR SIZE: 5.5 x 5 x 4.2 cm

TUMOR FOCALITY: Unifocal

MACROSCOPIC EXTENT OF TUMOR: Limited to kidney

HISTOLOGIC TYPE: Papillary renal cell carcinoma

SARCOMATOID FEATURES: Not identified.

TUMOR NECROSIS: Not identified.

HISTOLOGIC GRADE: Not applicable

[page 4 of 4]
THIS CONFIDENTIAL AND PRIVILEGED DOCUMENT/INFORMATION IS PROTECTED BY
FEDERAL AND STATE LAW. UNAUTHORIZED DISCLOSURE, DISSEMINATION
OR DUPLICATION IS PROHIBITED

Visit #: [REDACTED]

Page 4 of 4

Dual/Synchronous Primary Noted	Small Cell Lung	✓
Reviewed: [Signature]	Date Reviewed: 3/1/13	

Source: NCI Genomic Data Commons file 5f9dca84-2c75-4de5-997f-17356f8dca28 (TCGA-A4-A5Y1.25613DC3-ED19-47CD-AD6C-C900403D2E37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).